FM case AD15841 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/85c1eddf-1d56-4e59-b6a6-7f7c02aef087

Female, 66.7 years: Endometrioid adenocarcinoma, NOS (ICD-O-3 8380/3) of the ovary; metastasis biopsied or resected from the colon. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
